Gene-level copy-number profile of specimen HCM-BROD-0955-C15-85B from HCMI case HCM-BROD-0955-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; AJCC pathologic stage: Stage IVB; Tumor grade: G3; Age at diagnosis: 71.7 years (26,191 days).
Specimen HCM-BROD-0955-C15-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 5.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file b2eb05f4-1a9e-46bb-bd85-d2eed84f2e88.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0955-C15-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,714 have no estimate.
https://portal.gdc.cancer.gov/files/3c3f8e40-ba5d-4f35-9fe0-d5fb4eb26c83

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 3,609; copy number 2: 26,379; copy number 3: 19,688; copy number 4: 6,807; copy number 5: 1,343; copy number 6: 285; copy number 7: 370; copy number 8: 309; copy number 9: 51; copy number 10: 10; copy number 17: 19; copy number 55: 35.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:60,616,822–60,618,079, 2 genes (within-gene range 0–2): AC104164.2, MIR548BB.
- chr20:15,021,553–15,022,958, 2 genes (within-gene range 0–4): RNU6-1159P, RNU6-115P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,422 genes in 24 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,419,625–165,445,355, 884 genes, copy number 5 (broad region; genes not listed).
- chr4:73,710,302–73,871,308, 7 genes, copy number 5: UMLILO, CXCL8, AC112518.1, CXCL6, PPBPP1, PF4V1, CXCL1.
- chr5:30,248,350–41,510,628, 175 genes, copy number 5 (broad region; genes not listed).
- chr5:45,035,199–45,895,970, 5 genes, copy number 5: AC114954.1, HCN1, AC117529.2, AC117529.1, AC122694.1.
- chr7:7,356,203–7,620,543, 5 genes, copy number 5: COL28A1, AC004982.1, AC004982.2, MIOS, AC004948.1.
- chr7:92,560,758–103,514,007, 319 genes, copy number 5–7 (within-gene range 4–7) (broad region; genes not listed).
- chr7:103,484,208–103,484,539, 1 gene, copy number 7 (within-gene range 4–7): RN7SKP86.
- chr7:114,922,359–117,323,152, 52 genes, copy number 17–55: MDFIC, LINC01393, LINC01392, RAC1P6, Y_RNA, POLR2DP2, SNORA25B, AC092590.1, AC093714.1, AC093714.2, Y_RNA, TFEC, AC073130.3, TES, AC073130.2, AC002066.1, AC073130.1, CAV2, Metazoa_SRP, CAV1, AC006159.1, AC006159.2, COMETT, MET, CAPZA2, AC002543.1, Y_RNA, RNA5SP239, ST7-AS1, AC106873.5, AC106873.7, ST7, ST7-OT4, AC106873.8, AC106873.3, AC106873.2, AC106873.6, AC106873.4, AC106873.1, TPM3P1, MIR6132, ST7-AS2, AC002542.6, AC002542.2, AC002542.3, AC002542.1, AC002542.5, AC002542.4, AC006326.1, MTND4P6, MTCYBP6, WNT2.
- chr7:117,363,222–117,440,780, 2 genes, copy number 55: ASZ1, ANKRD49P4.
- chr9:71,862,452–73,751,077, 26 genes, copy number 5: ABHD17B, Y_RNA, C9orf85, HSPB1P1, C9orf57, AL583829.1, BTF3P4, GDA, AL135924.2, AL135924.1, RNA5SP285, LINC01504, ZFAND5, AL445646.1, AL596448.1, TMC1, RPS20P24, RPS27AP15, LINC01474, ALDH1A1, CYP1D1P, ANXA1, DPP3P2, AL451127.1, AL512594.1, RNA5SP286.
- chr12:112,405,190–112,418,838, 1 gene, copy number 5 (within-gene range 4–5): RPL6.
- chr13:27,066,156–27,488,232, 16 genes, copy number 5: USP12, AL158062.1, USP12-AS1, USP12-AS2, LINC02340, LINC00412, RPL21, SNORD102, SNORA27, RASL11A, RNU6-70P, LINC01079, RNY1P1, GTF3A, MTIF3, RNU6-63P.
- chr13:27,920,000–44,809,630, 272 genes, copy number 6–10 (broad region; genes not listed).
- chr13:45,120,510–45,284,893, 1 gene, copy number 8 (within-gene range 2–8): GTF2F2.
- chr13:45,192,853–53,939,960, 190 genes, copy number 6–9 (broad region; genes not listed).
- chr14:20,223,710–21,643,578, 99 genes, copy number 7 (broad region; genes not listed).
- chr16:25,419,812–28,772,807, 73 genes, copy number 5–8 (broad region; genes not listed).
- chr16:29,973,868–30,027,736, 5 genes, copy number 5 (within-gene range 4–5): TAOK2, HIRIP3, INO80E, DOC2A, C16orf92.
- chr16:30,053,090–31,095,980, 104 genes, copy number 5–7 (broad region; genes not listed).
- chr17:30,906,344–30,999,911, 9 genes, copy number 5 (within-gene range 4–5): ADAP2, AC138207.1, RN7SL138P, AC138207.5, AC138207.9, RNF135, AC138207.4, DPRXP4, AC138207.7.
- chr17:39,461,486–40,439,917, 51 genes, copy number 5–6 (within-gene range 4–6): CDK12, RNU6-233P, AC009283.1, NEUROD2, AC087491.1, PPP1R1B, STARD3, TCAP, PNMT, PGAP3, ERBB2, MIR4728, MIEN1, GRB7, IKZF3, KRT8P34, AC090844.1, ZPBP2, GSDMB, ORMDL3, AC090844.2, LRRC3C, GSDMA, PSMD3, AC090844.3, CSF3, MED24, MIR6884, SNORD124, THRA, NR1D1, AC068669.1, MSL1, CASC3, MIR6866, RAPGEFL1, MIR6867, WIPF2, CDC6, RARA, AC080112.4, RARA-AS1, AC080112.3, GJD3, AC080112.1, PPIAP54, RNA5SP441, AC080112.2, TOP2A, Y_RNA, RPL23AP75.
- chr17:71,011,997–71,298,218, 3 genes, copy number 6: AC005181.1, CASC17, RNU7-155P.
- chr19:14,566,078–14,612,035, 4 genes, copy number 7: NDUFB7, CLEC17A, RN7SL337P, RN7SL842P.
- chr19:15,159,038–17,287,646, 118 genes, copy number 6–8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 753. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
